Gene-level copy-number profile of tumor specimen ALCH-B1TB-TTP1-A from ALCHEMIST case ALCH-B1TB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.9 years (25,518 days).
Specimen ALCH-B1TB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 22db24e8-6d2b-4c70-b913-5b5979789993.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,260 have no estimate.
https://portal.gdc.cancer.gov/files/6d04ccb6-d60d-4bd1-b902-626b32535dcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 874; copy number 2: 54,367; copy number 3: 2,204; copy number 4: 605; copy number 5: 121; copy number 6: 78; copy number 7: 15; copy number 8: 4; copy number 9: 7; copy number 10: 5; copy number 11: 2; copy number 12: 6; copy number 13: 8; copy number 14: 6; copy number 18: 2; copy number 19: 2; copy number 20: 1; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,625,015–3,652,761, 2 genes (within-gene range 0–2): TPRG1L, WRAP73.
- chr1:13,222,705–13,248,652, 2 genes: PRAMEF18, PRAMEF31P.
- chr3:38,103,129–38,137,242, 2 genes (within-gene range 0–2): ACAA1, Y_RNA.
- chr3:38,265,812–38,278,757, 2 genes: SLC22A13, AP006193.1.
- chr3:75,328,549–75,435,110, 9 genes: MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP.
- chr4:188,159,705–188,161,157, 1 gene: LINC02434.
- chr5:135,120,526–135,139,681, 2 genes (within-gene range 0–2): AC008406.2, AC008406.1.
- chr5:138,285,265–138,338,355, 1 gene (within-gene range 0–1): CDC25C.
- chr5:160,195,744–160,204,826, 1 gene (within-gene range 0–1): FABP6-AS1.
- chr7:71,913,738–71,942,468, 2 genes (within-gene range 0–2): RNA5SP232, AC005011.1.
- chr7:154,838,388–154,865,483, 1 gene (within-gene range 0–2): AC073336.1.
- chr8:6,950,726–6,951,599, 1 gene: DEFA8P.
- chr8:6,996,766–7,018,297, 3 genes: DEFA1B, DEFT1P2, DEFA3.
- chr8:20,551,201–20,551,405, 1 gene: AC022559.1.
- chr9:136,647,872–136,660,421, 1 gene (within-gene range 0–10): AL590226.1.
- chr9:137,250,219–137,253,497, 2 genes: STPG3-AS1, STPG3.
- chr10:132,520,827–132,522,449, 1 gene: LINC01165.
- chr10:132,783,179–132,786,147, 1 gene (within-gene range 0–4): NKX6-2.
- chr11:1,947,278–2,001,470, 7 genes: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr12:51,186,936–51,217,708, 2 genes (within-gene range 0–1): POU6F1, AC139768.1.
- chr13:113,648,804–113,658,198, 1 gene: ATP4B.
- chr14:105,621,116–105,621,180, 1 gene: MIR8071-1.
- chr16:535,316–535,368, 1 gene (within-gene range 0–3): MIR5587.
- chr16:898,967–905,224, 1 gene (within-gene range 0–2): AL008727.1.
- chr16:2,204,248–2,209,453, 1 gene (within-gene range 0–5): MLST8.
- chr16:2,240,487–2,241,818, 1 gene (within-gene range 0–3): AC009065.8.
- chr16:32,185,624–32,193,530, 3 genes (within-gene range 0–1): AC133485.6, AC133485.5, AC133485.4.
- chr17:36,722,443–36,726,346, 1 gene: AC243830.1.
- chr18:37,473,330–37,473,977, 1 gene (within-gene range 0–1): AC129908.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 258 genes in 58 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,528,745–2,547,460, 2 genes, copy number 6–13: HES5, AL139246.5.
- chr1:2,555,639–2,569,888, 2 genes, copy number 5–11 (within-gene range 1–11): TNFRSF14, AL139246.2.
- chr1:2,635,976–2,801,717, 3 genes, copy number 13 (within-gene range 4–13): TTC34, AC242022.2, AC242022.1.
- chr1:13,172,455–13,179,464, 1 gene, copy number 8: PRAMEF9.
- chr3:152,243,828–152,465,780, 4 genes, copy number 5 (within-gene range 3–5): MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA.
- chr3:172,039,578–172,401,669, 4 genes, copy number 5: FNDC3B, RPS27AP8, RN7SL141P, AC092964.1.
- chr4:51,843,000–55,546,909, 71 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:39,105,252–39,274,528, 2 genes, copy number 5: FYB1, GOLGA5P1.
- chr5:181,306,502–181,342,213, 3 genes, copy number 7: AC138035.1, AC138035.3, AC138035.2.
- chr8:142,403,652–142,545,009, 2 genes, copy number 5–7: AC134682.1, ADGRB1.
- chr8:143,833,270–143,840,256, 2 genes, copy number 8: AC234917.1, AC234917.2.
- chr9:136,327,476–136,373,681, 3 genes, copy number 7–11: GPSM1, DNLZ, CARD9.
- chr9:136,658,856–136,672,678, 2 genes, copy number 10 (within-gene range 0–10): EGFL7, MIR126.
- chr9:136,721,366–136,728,184, 5 genes, copy number 14 (within-gene range 2–14): SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6.
- chr9:136,738,167–136,758,543, 2 genes, copy number 13–20: LCN10, LCN8.
- chr9:137,241,287–137,247,770, 2 genes, copy number 12: TUBB4B, FAM166A.
- chr11:1,157,953–1,262,172, 3 genes, copy number 6–9 (within-gene range 3–9): MUC5AC, MUC5B, MUC5B-AS1.
- chr12:990,509–1,495,933, 2 genes, copy number 5 (within-gene range 3–5): ERC1, HTR1DP1.
- chr12:9,852,984–9,870,136, 2 genes, copy number 6: CLEC2B, AC091814.1.
- chr12:10,030,678–10,066,031, 2 genes, copy number 5: CLEC9A, AC024224.1.
- chr12:10,358,464–10,410,146, 4 genes, copy number 5 (within-gene range 2–5): LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1.
- chr12:12,355,406–12,724,011, 14 genes, copy number 5: LOH12CR2, BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1.
- chr12:25,779,287–25,814,171, 3 genes, copy number 5: RN7SKP262, AC019209.3, TDGP1.
- chr12:26,623,369–27,446,625, 15 genes, copy number 5: AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1.
- chr12:27,523,431–27,756,295, 10 genes, copy number 5 (within-gene range 4–5): PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35.
- chr12:28,236,227–28,319,463, 2 genes, copy number 5: AC022079.1, RNU4-54P.
- chr14:105,152,194–105,181,323, 2 genes, copy number 9: AL512356.1, NUDT14.
- chr14:105,472,962–105,499,575, 4 genes, copy number 6–9: CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,546,610–105,626,066, 4 genes, copy number 5–29 (within-gene range 0–29): ELK2BP, IGHA2, IGHE, IGHG4.
- chr14:105,639,559–105,649,057, 3 genes, copy number 7: IGHG2, MIR8071-2, COPDA1.
- chr16:396,725–412,487, 2 genes, copy number 18: NME4, DECR2.
- chr16:560,394–769,443, 29 genes, copy number 5–19 (within-gene range 1–19): PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1.
- chr16:2,140,803–2,196,605, 6 genes, copy number 7–12: RAB26, SNHG19, SNORD60, AC009065.9, TRAF7, CASKIN1.
- chr16:2,209,253–2,238,711, 6 genes, copy number 5–6 (within-gene range 0–6): BRICD5, PGP, AC009065.7, E4F1, AC009065.1, DNASE1L2.
- chr16:32,356,981–32,380,049, 2 genes, copy number 10: AC133548.1, ACTR3BP3.
- chr19:1,103,926–1,174,268, 2 genes, copy number 6–7: GPX4, SBNO2.
- chr19:1,248,553–1,279,244, 4 genes, copy number 5–12 (within-gene range 5–18): MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,554,669–1,592,865, 2 genes, copy number 5 (within-gene range 4–5): MEX3D, MBD3.
- chr19:2,071,036–2,099,593, 2 genes, copy number 5: MOB3A, IZUMO4.
- chr20:63,528,001–63,574,239, 5 genes, copy number 8–13: PTK6, SRMS, AL121829.2, FNDC11, HELZ2.

Autosomal genes at a single copy (total copy number 1): 874. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
